CCDI case PBBZDU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/6b748a3f-63e9-4625-8f73-20d029243329

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 24.8 years (9,059 days).

Biospecimens (2 samples)
- Sample 0DLIF8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLIFO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
